FM case AD5766 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/e468f304-7b41-4e13-803a-02e069b961ee

Male, 56.8 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
